Somatic mutation profile of tumor specimen ALCH-ADOB-TTP1-A (aliquot ALCH-ADOB-TTP1-A-1-0-D-A532-36) from ALCHEMIST case ALCH-ADOB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.4 years (25,357 days).
Specimen ALCH-ADOB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6057aff6-3d9f-45ec-b074-855f6b59033a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADOB-NB1-A (Blood Derived Normal), aliquot ALCH-ADOB-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b227d8eb-1a77-4604-a497-1fe7c2813e74

The open-access MAF lists 127 somatic variants for this specimen: 94 protein-altering or splice-affecting, 20 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 20, Nonsense Mutation 7, Frame Shift Del 6, Intron 6, RNA 3, In Frame Del 2, 3'UTR 2, 5'Flank 2, Splice Site 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 129/757 reads (17%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- ABCA12 | c.5362G>T p.E1788* (on ENST00000272895 / NM_173076.3; = p.E1470* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 90/450 reads (20%) | catalogued as COSV99789601; called by muse, mutect2, varscan2
- ADAMTS12 | c.1325G>T p.R442L | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61257592; called by muse, mutect2, varscan2
- AP1M1 | c.801C>A p.Y267* | Nonsense Mutation (SNP) | VAF 32/144 reads (22%) | catalogued as rs368590185; called by muse, mutect2, varscan2
- BMPR2 | c.782T>C p.I261T | Missense Mutation (SNP) | VAF 34/576 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs1444294857, CD106884; called by muse, mutect2
- CCDC154 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs763953899, COSV51973147; called by mutect2, varscan2
- CD1E | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV100937076; called by muse, mutect2, varscan2
- COL12A1 | c.8233A>G p.S2745G | Missense Mutation (SNP) | VAF 88/406 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs1244382961; called by muse, mutect2, varscan2
- CRX | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55757289; called by muse, mutect2
- DACT1 | c.1475G>C p.R492T | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60020571; called by muse, mutect2, varscan2
- DNAH5 | c.2489C>G p.A830G | Missense Mutation (SNP) | VAF 34/573 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1226712032; called by muse, mutect2
- DSEL | c.3331C>T p.H1111Y | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as COSV59490898; called by muse, mutect2
- GPR19 | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.432); catalogued as rs771726052; called by muse, mutect2, varscan2
- HIVEP1 | c.1525G>T p.G509C | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV101045617; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1443C>A p.Y481* | Nonsense Mutation (SNP) | VAF 207/815 reads (25%) | catalogued as COSV56293571; called by muse, mutect2, varscan2
- KIAA1755 | c.3016G>T p.A1006S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.211); catalogued as rs1404978225; called by muse, mutect2, varscan2
- MFSD2B | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs374612098; called by muse, varscan2
- MTPN | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.137); catalogued as COSV67599999; called by muse, mutect2, varscan2
- NAA35 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs751698413; called by muse, varscan2
- OR10W1 | c.326T>A p.M109K | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182065854; called by muse, mutect2, varscan2
- PARP14 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as rs377384462; called by muse, mutect2
- PCDHA3 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 281/799 reads (35%) | catalogued as COSV63541527; called by muse, mutect2, varscan2
- PITPNM2 | c.3344C>T p.S1115F | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54909419; called by muse, mutect2, varscan2
- PLA2G6 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 89/268 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); catalogued as rs149653983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCG | c.1682A>T p.E561V | Missense Mutation (SNP) | VAF 21/427 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV54731367; called by muse, mutect2
- USH2A | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs777682016, CM163301, COSV56418820; called by muse, mutect2, varscan2
- USP27X | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 36/597 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as COSV71200898; called by muse, mutect2
- VWA8 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); catalogued as COSV99864089; called by muse, mutect2
- WDR87 | c.4655G>A p.R1552Q | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs772097471, COSV58193274; called by muse, mutect2, varscan2
- ZNF3 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52795742; called by muse, mutect2
- ZNF516 | c.1669G>C p.G557R | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV71587763; called by muse, mutect2, varscan2
- ZNF668 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100336951; called by muse, mutect2, varscan2
- AASDH | c.1071G>C p.R357S | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- ADGRL2 | c.2299C>G p.L767V (on ENST00000370717 / NM_001366005.1; = p.L754V on NM_012302.4) | Missense Mutation (SNP) | VAF 12/347 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2
- ALPK1 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- ALYREF | c.266A>T p.Q89L | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2
- ANKRD36 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ARR3 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CCDC110 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); called by muse, mutect2
- CCDC8 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 226/963 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDHR2 | c.2138T>C p.V713A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CENPF | c.5182G>T p.D1728Y | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CNTNAP5 | c.574_578del p.R192Qfs*53 | Frame Shift Del (DEL) | VAF 77/463 reads (17%) | called by mutect2, pindel, varscan2
- COL14A1 | c.4181T>G p.V1394G | Missense Mutation (SNP) | VAF 46/630 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2
- COL6A3 | c.6781G>A p.G2261R | Missense Mutation (SNP) | VAF 195/660 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPLANE2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2
- CXCL6 | c.222G>T p.Q74H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- DENND3 | c.488T>A p.L163H | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND3 | c.1605_1621del p.H536Efs*11 | Frame Shift Del (DEL) | VAF 78/486 reads (16%) | called by mutect2, pindel, varscan2
- EGR4 | c.1313G>A p.S438N (on ENST00000545030; = p.S335N on NM_001965.4) | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ESRP1 | c.1599_1614del p.M533Ifs*40 | Frame Shift Del (DEL) | VAF 58/316 reads (18%) | called by mutect2, pindel
- EYS | c.1778C>A p.S593Y | Missense Mutation (SNP) | VAF 86/364 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGD4 | c.994-8C>T | Splice Region (SNP) | VAF 82/456 reads (18%) | called by muse, varscan2
- FGD4 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 104/548 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- GRIK5 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- HEXA | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 22/693 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRP1 | c.11509C>A p.L3837I | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- MED12 | c.2080G>T p.E694* | Nonsense Mutation (SNP) | VAF 53/275 reads (19%) | called by muse, mutect2, varscan2
- MIEN1 | c.42del p.E15Rfs*32 | Frame Shift Del (DEL) | VAF 25/141 reads (18%) | called by mutect2, pindel, varscan2
- MS4A8 | c.477T>A p.D159E | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2
- NES | c.2019G>C p.E673D | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NFE2L3 | c.1837T>G p.L613V | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP12 | c.708C>G p.D236E | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OAZ2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 61/125 reads (49%) | called by muse, mutect2, varscan2
- OTULINL | c.825G>C p.E275D | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OXCT1 | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 79/426 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, varscan2
- PEAK1 | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 24/199 reads (12%) | called by muse, mutect2, varscan2
- POLA2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 53/229 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PPM1E | c.934G>C p.V312L | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2
- PPP1R3A | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSG5 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.189); called by muse, mutect2
- RBM12B | c.888_891del p.D296Efs*4 | Frame Shift Del (DEL) | VAF 61/224 reads (27%) | called by mutect2, pindel, varscan2
- RBM14 | c.1855G>C p.E619Q | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SEMA4D | c.2033A>T p.Q678L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A3 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 17/478 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SNRPB2 | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SOWAHC | c.1002C>G p.I334M | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SOWAHC | c.1259_1267del p.P420_H422del | In Frame Del (DEL) | VAF 40/296 reads (14%) | called by mutect2, pindel, varscan2
- SPAG9 | c.2945A>G p.Y982C (on ENST00000262013 / NM_001130528.3; = p.Y968C on NM_003971.6) | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SPTA1 | c.6121-33_6121del p.X2041_splice | Splice Site (DEL) | VAF 28/340 reads (8%) | called by mutect2, pindel
- SSC5D | c.1905T>A p.N635K | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- SWT1 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 138/327 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TCERG1L | c.1737A>T p.R579S | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TERT | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2
- TGFA | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TOM1L1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 88/435 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TRIM23 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 24/594 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.156); called by muse, mutect2
- TSC22D2 | c.1138T>C p.Y380H | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ZC3HAV1 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2
- ZFAT | c.1518C>A p.D506E | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.32); called by muse, mutect2
- ZNF536 | c.1396C>A p.L466M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- ZNF674 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 73/503 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.3556C>A p.P1186T | Missense Mutation (SNP) | VAF 89/415 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZXDC | c.2328del p.P777Qfs*96 | Frame Shift Del (DEL) | VAF 41/209 reads (20%) | called by mutect2, pindel, varscan2
- ABCA12 | c.7050A>G p.E2350= (on ENST00000272895 / NM_173076.3; = p.E2032= on NM_015657.3) | Silent (SNP) | VAF 20/548 reads (4%) | called by muse, mutect2
- CCDC40 | c.660C>T p.F220= | Silent (SNP) | VAF 117/483 reads (24%) | catalogued as rs200678214; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD101 | c.1506C>T p.A502= | Silent (SNP) | VAF 34/463 reads (7%) | called by muse, mutect2
- CHRNG | c.315C>T p.T105= | Silent (SNP) | VAF 79/271 reads (29%) | catalogued as COSV51322717; called by muse, mutect2, varscan2
- CIAO3 | c.606C>A p.G202= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- COL27A1 | c.1527T>G p.P509= | Silent (SNP) | VAF 51/127 reads (40%) | called by muse, mutect2, varscan2
- DCAF15 | c.1026C>G p.A342= | Silent (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- DPP6 | c.423C>T p.F141= (on ENST00000377770 / NM_001364500.2; = p.F79= on NM_001936.5) | Silent (SNP) | VAF 18/315 reads (6%) | catalogued as COSV59630077; called by muse, mutect2
- DPY19L3 | c.1623A>T p.P541= | Silent (SNP) | VAF 69/281 reads (25%) | called by muse, mutect2, varscan2
- LDB2 | c.198C>A p.T66= | Silent (SNP) | VAF 57/494 reads (12%) | called by muse, mutect2, varscan2
- OR10G8 | c.831G>T p.V277= | Silent (SNP) | VAF 22/158 reads (14%) | called by muse, mutect2, varscan2
- OTUD6A | c.600C>T p.Y200= | Silent (SNP) | VAF 84/385 reads (22%) | catalogued as COSV57973362; called by muse, mutect2, varscan2
- PLXNC1 | c.1476C>T p.N492= | Silent (SNP) | VAF 55/301 reads (18%) | called by muse, mutect2, varscan2
- PRSS35 | c.759G>T p.R253= | Silent (SNP) | VAF 46/216 reads (21%) | called by muse, mutect2, varscan2
- SLFN5 | c.72G>A p.G24= | Silent (SNP) | VAF 58/247 reads (23%) | called by muse, mutect2, varscan2
- SNX12 | c.369C>A p.L123= | Silent (SNP) | VAF 141/539 reads (26%) | catalogued as COSV52145449; called by muse, mutect2, varscan2
- ST3GAL1 | c.885G>C p.G295= | Silent (SNP) | VAF 73/182 reads (40%) | called by muse, mutect2, varscan2
- THADA | c.3894A>G p.K1298= | Silent (SNP) | VAF 34/171 reads (20%) | called by muse, mutect2, varscan2
- THBS1 | c.3189G>T p.V1063= | Silent (SNP) | VAF 22/461 reads (5%) | catalogued as rs1272261564; called by muse, mutect2
- WNK1 | c.1431C>T p.A477= | Silent (SNP) | VAF 18/351 reads (5%) | called by muse, mutect2
- ALG1 | chr16:5071831 C>T | 5'Flank (SNP) | VAF 37/219 reads (17%) | catalogued as rs1007953081; called by muse, mutect2, varscan2
- AZI2 | c.647+456C>T | Intron (SNP) | VAF 105/403 reads (26%) | catalogued as rs770348443; called by muse, varscan2
- CASC3 | c.259+31A>G | Intron (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
- CHN2 | c.577-27C>T | Intron (SNP) | VAF 396/1188 reads (33%) | called by muse, mutect2, varscan2
- DPP6 | c.244-140720C>A | Intron (SNP) | VAF 36/127 reads (28%) | catalogued as COSV100125448; called by muse, varscan2
- EIF3IP1 | n.305G>T | RNA (SNP) | VAF 104/494 reads (21%) | called by muse, mutect2, varscan2
- FAM205BP | n.1369A>T | RNA (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2
- GPATCH8 | c.*1787C>T | 3'UTR (SNP) | VAF 32/1034 reads (3%) | called by muse, mutect2
- NRG1 | c.502+31212C>A | Intron (SNP) | VAF 87/244 reads (36%) | called by muse, mutect2, varscan2
- RPL13AP20 | n.165G>T | RNA (SNP) | VAF 114/387 reads (29%) | called by muse, mutect2, varscan2
- SMIM29 | c.*174C>T | 3'UTR (SNP) | VAF 28/81 reads (35%) | catalogued as rs1272510746; called by muse, mutect2, varscan2
- SPEF2 | c.4448-3180A>C | Intron (SNP) | VAF 16/285 reads (6%) | called by muse, mutect2
- ZNF598 | chr16:2010040 T>C | 5'Flank (SNP) | VAF 31/175 reads (18%) | called by muse, mutect2, varscan2
